Somatic mutation profile of tumor specimen ASCProject_0134_T2_WES (aliquot ASCProject_0134_T2_WES_1) from CMI case ASCProject_0134, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 62.8 years (22,935 days).
Specimen ASCProject_0134_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Forehead; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e9dce3e-a877-4c7c-be0f-a5e831e101ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0134_SALIVA (Saliva), aliquot ASCProject_0134_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9359de72-c437-42bc-b839-931b4e65579f

The open-access MAF lists 233 somatic variants for this specimen: 155 protein-altering or splice-affecting, 59 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 59, Intron 7, Nonsense Mutation 7, Splice Region 6, RNA 4, Splice Site 3, 5'UTR 3, 5'Flank 3, Frame Shift Del 2, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.838A>G p.R280G | Missense Mutation (SNP) | VAF 65/291 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753660142, COSV52662754, COSV52708728, COSV52851287; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 79/352 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55966863, COSV99714182; called by muse, mutect2, varscan2
- AFF3 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485483467; called by muse, mutect2
- AHNAK2 | c.16672G>A p.G5558R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.189); catalogued as COSV100317438; called by muse, mutect2
- AIRE | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs200540137; called by muse, mutect2, varscan2
- ANAPC7 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466099904; called by muse, mutect2, varscan2
- BICRAL | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as COSV100018051; called by muse, mutect2
- C3orf14 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.082); catalogued as COSV51706445, COSV51707350; called by muse, mutect2
- C6orf58 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 21/247 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61666049; called by muse, mutect2
- CECR2 | c.3502G>A p.G1168R (on ENST00000342247 / NM_001290047.2; = p.G984R on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.66); catalogued as rs1373203762; called by muse, mutect2, varscan2
- CFAP43 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.143); catalogued as rs780370047, COSV53380099; called by muse, mutect2, varscan2
- COL10A1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572843; called by muse, mutect2, varscan2
- COL19A1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59573948; called by muse, mutect2, varscan2
- DEDD2 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60142419; called by muse, mutect2
- DGKG | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs973327725; called by muse, mutect2
- DIP2B | c.3541C>T p.R1181* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as rs1565884128, COSV99999162; called by muse, mutect2
- DPF3 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.639); catalogued as rs377366846; called by muse, mutect2, varscan2
- DPY19L3 | c.1404A>G p.I468M | Missense Mutation (SNP) | VAF 13/236 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1256963812; called by muse, mutect2
- DST | c.3278C>T p.P1093L (on ENST00000361203 / NM_001374722.1; = p.P767L on NM_001723.6) | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs778194334, COSV55037410; called by muse, mutect2, varscan2
- DTX3L | c.1887del p.F630Lfs*5 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as COSV56145925; called by mutect2, pindel, varscan2
- DTX4 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs61735920; called by muse, mutect2, varscan2
- EHMT2 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs772988696; called by muse, varscan2
- EMILIN1 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1176609847; called by muse, mutect2
- EPHA3 | c.2387T>A p.I796K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60706263, COSV60727761; called by muse, mutect2, varscan2
- EXOC3 | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV59268928; called by muse, mutect2
- FAM135B | c.3439G>A p.G1147S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424442; called by muse, mutect2
- FAM81B | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV51981627; called by muse, mutect2, varscan2
- FOXQ1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1423195847; called by muse, varscan2
- FTMT | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV58420771; called by muse, mutect2
- GGT7 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.264); catalogued as rs1171478210, COSV60540401; called by muse, mutect2, varscan2
- GHR | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as COSV50109797; called by muse, mutect2, varscan2
- GRIK5 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.736); catalogued as rs1296021976, COSV53475430; called by muse, mutect2
- HMOX2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs567262048; called by muse, mutect2, varscan2
- HRNR | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as rs1274470104; called by muse, mutect2
- HSPG2 | c.6127C>T p.L2043F | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as COSV101020954; called by muse, mutect2
- IGSF1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs201712796, COSV63836956; called by muse, mutect2, varscan2
- KIAA1109 | c.11780C>T p.P3927L | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs761199287; called by muse, mutect2, varscan2
- KIR2DL3 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1325006558; called by muse, mutect2
- MATN2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.893); catalogued as rs752673896, COSV54714418; called by muse, mutect2, varscan2
- MTMR9 | c.356T>G p.V119G | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.071); catalogued as rs777793737; called by muse, mutect2
- MTNR1B | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs565670988, CM121604, COSV57068231; called by muse, mutect2, varscan2
- MYH3 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1407060765; called by muse, mutect2, varscan2
- MYO18B | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1444704245; called by muse, mutect2, varscan2
- MYO3A | c.3101G>A p.G1034E | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56322680, COSV56327783; called by muse, mutect2
- MYOM3 | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58397423; called by muse, mutect2
- NIPAL4 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV61729967; called by muse, mutect2
- NOS1 | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57610112, COSV57621737; called by muse, mutect2
- OR2T27 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61282687; called by muse, mutect2, varscan2
- OR8H2 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57943415; called by muse, mutect2
- PCDHGA2 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1423721423, COSV53981061; called by muse, mutect2, varscan2
- PHF2 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs915369911; called by muse, mutect2
- PIH1D2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54775348; called by muse, mutect2
- PLA2G15 | c.126G>T p.L42= | Splice Region (SNP) | VAF 10/85 reads (12%) | catalogued as COSV54722139; called by muse, mutect2, varscan2
- PTPRO | c.2504G>A p.G835E | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99840107; called by muse, mutect2
- RXFP2 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV53633477; called by muse, mutect2
- RYR2 | c.13397A>C p.H4466P | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.287); catalogued as COSV63669834; called by muse, mutect2
- SETD2 | c.6604C>T p.P2202S | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs143083979, COSV57431003, COSV57431948; called by muse, mutect2, varscan2
- SLC23A2 | c.1384G>A p.G462R | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595284, COSV57772571; called by muse, mutect2
- SLC5A8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867168951, COSV101610512, COSV73310407; called by muse, mutect2, varscan2
- SLX4 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs199929086; called by muse, mutect2, varscan2
- SMC5 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 12/264 reads (5%) | catalogued as rs1341391383; called by muse, mutect2
- SRPK3 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs782367006; called by mutect2, varscan2
- STMN4 | c.209C>G p.P70R (on ENST00000265770 / NM_001283054.2; = p.P97R on NM_030795.4) | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56108227; called by muse, mutect2, varscan2
- TBX10 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226140206; called by muse, mutect2, varscan2
- TBX20 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101282370, COSV68782525; called by muse, mutect2, varscan2
- TMCC3 | c.971A>G p.Q324R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV99705668; called by mutect2, varscan2
- UGT1A9 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV60855274; called by muse, mutect2
- UNC13D | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.532); catalogued as CD1514505; called by muse, mutect2
- WFIKKN2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs748492095; called by muse, mutect2, varscan2
- ZNF674 | c.490A>G p.R164G | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs200601841; called by mutect2, varscan2
- ABCA8 | c.3430-4G>T | Splice Region (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- ACTN4 | c.165C>T p.T55= | Splice Region (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- ADAMTS12 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ADAMTS18 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- AHNAK2 | c.16673G>A p.G5558E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.327); called by muse, mutect2
- AKR1C8P | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, varscan2
- ALB | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANAPC7 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA1 | c.458A>C p.N153T | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- ARHGAP24 | c.577G>A p.G193R (on ENST00000395184 / NM_001025616.3; = p.G100R on NM_031305.3) | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL3 | c.3040-1G>A p.X1014_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ATP10D | c.2577G>T p.R859S | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRINP2 | c.461-1G>A p.X154_splice | Splice Site (SNP) | VAF 21/233 reads (9%) | called by muse, mutect2
- BRSK2 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, varscan2
- BTN3A3 | c.154T>G p.C52G | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1I | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CAMK4 | c.387G>A p.R129= | Splice Region (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- CARMIL1 | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCNA1 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, mutect2
- CEP112 | c.1152G>T p.L384F | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLCA4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTCFL | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DBX1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DUOX2 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EML6 | c.4338G>A p.W1446* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | called by muse, varscan2
- EPG5 | c.2408A>G p.Y803C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- FERMT1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRG3 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLB1L3 | c.418A>C p.N140H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- HERC1 | c.4208G>A p.R1403K | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2
- HMCN1 | c.12586C>T p.P4196S | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA3 | c.2198A>T p.Q733L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KIAA1109 | c.11779C>A p.P3927T | Missense Mutation (SNP) | VAF 89/447 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- KIF7 | c.3657C>A p.H1219Q | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KLHL1 | c.1075C>T p.H359Y | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.236); called by muse, mutect2
- KRT83 | c.905A>T p.Y302F | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2
- LIG4 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC74B | c.415+4G>A | Splice Region (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- MAP3K9 | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEGF8 | c.6136C>T p.P2046S (on ENST00000251268 / NM_001271938.2; = p.P1979S on NM_001410.3) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MGAM | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- MOXD1 | c.1334A>C p.Y445S | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MROH1 | c.4776G>A p.G1592= | Splice Region (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- MUCL3 | c.1066C>T p.P356S (on ENST00000304311; = p.P1232S on NM_080870.4) | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- MYCBP2 | c.7201G>A p.E2401K (on ENST00000357337; = p.E2439K on NM_015057.5) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MYOM2 | c.3637C>T p.L1213F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAA16 | c.2211G>A p.M737I | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEDD1 | c.831A>T p.L277F | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NOTCH2 | c.6043T>C p.F2015L | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR5H1 | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- PAX4 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PCSK1 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDZD2 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 15/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD4 | c.1988A>C p.D663A | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PFN2 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLEKHG4B | c.527C>T p.P176L (on ENST00000283426; = p.P532L on NM_052909.5) | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNPLA7 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PROM2 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- PSD2 | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RAB40AL | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA2 | c.3917T>G p.V1306G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, varscan2
- SCRN1 | c.599_605del p.E200Gfs*32 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- SELE | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SENP6 | c.3067C>T p.Q1023* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- SIX4 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SLC5A8 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, varscan2
- SLC6A11 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- SLCO1B1 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- SOGA3 | c.1355A>C p.H452P | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THUMPD2 | c.869T>C p.M290T | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMEM232 | c.534A>G p.I178M | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- TRIP12 | c.5493T>G p.N1831K | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); called by muse, mutect2
- TSGA10 | c.1089A>T p.K363N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- TUBA4B | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- UNC80 | c.2449C>A p.R817S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); called by muse, mutect2
- VCAN | c.3547G>A p.G1183R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13D | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- VPS13D | c.9553G>A p.V3185I | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- WAC | c.1519C>G p.H507D | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- XPNPEP1 | c.1617T>G p.N539K | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZAN | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZFP64 | c.172+1G>A p.X58_splice | Splice Site (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- ZNF227 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ANK3 | c.2751C>T p.F917= (on ENST00000280772 / NM_001320874.2; = p.F51= on NM_001149.3) | Silent (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- BBS5 | c.12G>A p.L4= | Silent (SNP) | VAF 36/277 reads (13%) | called by muse, mutect2, varscan2
- BCL11B | c.1182C>T p.P394= (on ENST00000357195 / NM_001282237.2; = p.P323= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs766752148; called by muse, mutect2, varscan2
- CACNA1S | c.2538G>A p.E846= | Silent (SNP) | VAF 33/216 reads (15%) | catalogued as COSV62942270; called by muse, varscan2
- CD163L1 | c.852G>A p.G284= | Silent (SNP) | VAF 29/249 reads (12%) | catalogued as rs772048774; called by muse, mutect2, varscan2
- CEACAM4 | c.489G>A p.G163= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- CES1 | c.927G>A p.Q309= | Silent (SNP) | VAF 34/305 reads (11%) | called by muse, mutect2, varscan2
- CNGB3 | c.2358C>A p.I786= | Silent (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- CTC1 | c.3405C>T p.D1135= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs755058193; called by muse, mutect2, varscan2
- DDI1 | c.1146G>A p.K382= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs781374012; called by muse, varscan2
- FMO2 | c.1038G>A p.E346= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV52946798; called by muse, mutect2
- FRYL | c.5124C>T p.D1708= | Silent (SNP) | VAF 28/327 reads (9%) | catalogued as rs1346660722; called by muse, mutect2
- GPC5 | c.648G>A p.G216= | Silent (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- GUCA1C | c.519C>T p.F173= | Silent (SNP) | VAF 18/300 reads (6%) | catalogued as rs1028693252, COSV53756567; called by muse, mutect2
- HCN4 | c.1893G>A p.K631= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- HDAC8 | c.675C>T p.Y225= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- IL17RA | c.1422C>T p.P474= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- IRF5 | c.1152G>A p.K384= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs961082732, COSV50860914, COSV50861104; called by muse, mutect2, varscan2
- KCP | c.435C>T p.Y145= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs909358331, COSV52822328; called by muse, mutect2, varscan2
- KRTAP13-2 | c.441C>T p.C147= | Silent (SNP) | VAF 18/231 reads (8%) | called by muse, mutect2
- KSR2 | c.1929G>A p.R643= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV56664620; called by muse, mutect2, varscan2
- LARP1 | c.60C>T p.F20= | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as COSV60430163; called by muse, mutect2, varscan2
- MAGEE1 | c.753C>T p.T251= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs879988996; called by muse, mutect2, varscan2
- MAST4 | c.7569C>T p.S2523= (on ENST00000403625 / NM_001164664.2; = p.S2334= on NM_015183.3) | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as rs371863172; called by muse, mutect2, varscan2
- MUC4 | c.12285C>T p.T4095= | Silent (SNP) | VAF 24/241 reads (10%) | catalogued as rs559831827; called by muse, varscan2
- MUC5AC | c.966G>A p.G322= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- MYO18B | c.4728G>A p.R1576= | Silent (SNP) | VAF 23/245 reads (9%) | catalogued as rs1257038016, COSV59135018; called by muse, mutect2
- MYPN | c.3945G>A p.V1315= | Silent (SNP) | VAF 22/377 reads (6%) | catalogued as rs267602553; called by muse, mutect2
- NDST1 | c.2205C>T p.T735= | Silent (SNP) | VAF 19/264 reads (7%) | catalogued as rs759703382; called by muse, mutect2
- NOMO1 | c.3300C>T p.F1100= | Silent (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- NPC2 | c.405C>T p.N135= | Silent (SNP) | VAF 56/313 reads (18%) | called by muse, mutect2, varscan2
- ODF1 | c.477C>T p.D159= | Silent (SNP) | VAF 16/437 reads (4%) | catalogued as COSV53432612; called by muse, mutect2
- OR2H2 | c.78C>T p.F26= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs749678413; called by muse, mutect2, varscan2
- OR6P1 | c.51C>T p.F17= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV58109490; called by muse, mutect2, varscan2
- OR7A10 | c.189C>T p.L63= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs202143392, COSV50166131; called by muse, mutect2, varscan2
- OSBPL7 | c.1461C>T p.I487= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs765052315; called by muse, mutect2
- PARP8 | c.1803C>T p.N601= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- PCDHB11 | c.1935G>A p.K645= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- PIFO | c.372G>A p.K124= | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- PNMA8A | c.579G>A p.G193= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1262977835; called by muse, mutect2, varscan2
- PRC1 | c.729C>T p.I243= | Silent (SNP) | VAF 22/252 reads (9%) | called by muse, mutect2
- PRICKLE2 | c.2065C>T p.L689= (on ENST00000295902; = p.L633= on NM_198859.4) | Silent (SNP) | VAF 53/190 reads (28%) | catalogued as rs576746551; called by muse, mutect2, varscan2
- PRPH | c.1167G>A p.L389= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- ROCK1 | c.3345C>T p.N1115= | Silent (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2
- SCN1A | c.1470T>C p.S490= | Silent (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- SELE | c.1353C>T p.F451= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV60974702, COSV60976273; called by muse, mutect2, varscan2
- SERPINB7 | c.1056C>T p.S352= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV100321052; called by muse, mutect2
- SIRPB1 | c.501C>T p.F167= | Silent (SNP) | VAF 31/288 reads (11%) | catalogued as COSV99498570; called by muse, mutect2, varscan2
- SLC22A18 | c.927G>A p.R309= | Silent (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
- SLC6A15 | c.2103C>T p.S701= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- SMLR1 | c.249A>G p.E83= | Silent (SNP) | VAF 15/172 reads (9%) | catalogued as rs1227564305; called by muse, mutect2
- SPATA21 | c.534G>A p.R178= | Silent (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- TGIF2LX | c.165A>G p.G55= | Silent (SNP) | VAF 46/223 reads (21%) | called by muse, mutect2, varscan2
- TMEM236 | c.555C>T p.N185= | Silent (SNP) | VAF 128/618 reads (21%) | catalogued as rs1446749397; called by muse, mutect2, varscan2
- USP34 | c.5370C>T p.L1790= | Silent (SNP) | VAF 49/297 reads (16%) | catalogued as rs757783347; called by muse, mutect2, varscan2
- WDR81 | c.1572C>T p.F524= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as rs1464979783; called by muse, mutect2, varscan2
- WWC1 | c.999G>T p.V333= | Silent (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- YIF1B | c.204C>T p.P68= (on ENST00000339413 / NM_001039673.3; = p.P53= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- ZXDC | c.2355G>C p.V785= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- AC125421.1 | n.325-207C>T | Intron (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.1202G>A | RNA (SNP) | VAF 26/275 reads (9%) | called by muse, mutect2
- ASIC4 | c.1018+526C>T | Intron (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- BMP7 | c.1036-22C>T | Intron (SNP) | VAF 37/213 reads (17%) | called by muse, mutect2, varscan2
- CLRN1 | c.*1280G>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | catalogued as rs1310561415; called by muse, varscan2
- CYP2A7P2 | n.87G>A | RNA (SNP) | VAF 10/98 reads (10%) | catalogued as rs1210492230; called by muse, mutect2
- DNAH14 | c.1032+140C>T | Intron (SNP) | VAF 12/123 reads (10%) | catalogued as rs1335581482, COSV100835884; called by muse, mutect2
- HBD | chr11:5232764 C>T | 3'Flank (SNP) | VAF 18/246 reads (7%) | catalogued as rs567792872; called by muse, mutect2
- HSP90AA4P | n.2085T>C | RNA (SNP) | VAF 28/154 reads (18%) | called by muse, mutect2, varscan2
- IRAG2 | c.3001+14G>A | Intron (SNP) | VAF 18/169 reads (11%) | catalogued as rs1269317250; called by muse, mutect2, varscan2
- MAP4 | c.2000-14582C>T | Intron (SNP) | VAF 10/94 reads (11%) | catalogued as COSV53139807; called by muse, mutect2, varscan2
- NFYC | c.828+18A>G | Intron (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- NREP | c.-23C>T | 5'UTR (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- RINT1 | c.-25A>G | 5'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- RNU6-104P | chr8:43300593 G>A | 5'Flank (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- SCP2D1 | chr20:18809961 C>T | 5'Flank (SNP) | VAF 30/246 reads (12%) | called by muse, mutect2, varscan2
- SNORD115-38 | n.81C>T | RNA (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- STX8 | chr17:9575840 C>T | 5'Flank (SNP) | VAF 12/83 reads (14%) | catalogued as rs573546672; called by muse, mutect2, varscan2
- UNG | c.-8G>T | 5'UTR (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
